Surgical pathology report (de-identified scan), TCGA case TCGA-59-2350, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Roswell Park, specimen TCGA-59-2350-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY HISTORY REPORT

DISCLAIMER

THIS IS A HISTORY CASE THAT YOU CANNOT EDIT. TO SEE THE ENTIRE TEXT PLEASE GO TO THE PATIENT HISTORY BY CLICKING THE ELLIPSE (...) NEXT TO THE PATIENT NAME AND CLICKING ON THE HISTORY TAB

DIAGNOSIS:

Ovarian carcinoma with ascites. 0 treatment.

FINAL DIAGNOSIS:

1. OMENTUM WITH TUMOR: Positive for METASTASES (See note).
2. UTERUS, TUBES, OVARIES, UPPER VAGINA, PARAMETRIUM, CUL-DE-SAC TUMOR:
- A) BILATERAL OVARAIN SEROUS PAPILLARY ADENOCARCINOMA, Grade 2-3 with:
- Diffuse involvement of OVARIAN SEROSAE, UTERINE SEROSAE, CERVICAL WALL (outer third), PARAMETRIA, CUL-DE-SAC
- INTRAMUCOSAL METASTASIS to RIGHT FALLOPIAN TUBE and BOTH TUBAL SEROSAE
- EXTENSIVE LYMPHATIC and VASCULAR METASTASES (WITHIN OVARY)
- B) LEIOMYOMATA, UTERI
- C) SQUAMOUS METAPLASIA, CERVIX
- D) MID-SECRETORY ENDOMETRIUM
3. TUMOR, ANTERIOR RECTAL WALL: Positive for METASTASIS.
See note.
4. BLADDER, PERITONEUM with TUMOR: Positive for METASTASIS.
See note.
5. DESCENDING COLON & RECTAL SIGMOID: Positive for METASTASIS.
See note.

[page 2 of 4]
[REDACTED]

6. OMENTAL TUMOR @ SPLEEN: Positive for METASTASIS.

See note.

7. PROXIMAL JEJUNAL MESENTERIC NODULE: Positive for METASTASIS.

See note.

8. DISTAL ILEUM MESENTERIC NODULE: Positive for METASTASIS.

See note.

9. TUMOR FROM RIGHT HEPATIC FLEXURE: Positive for METASTASIS.

See note.

10. TUMOR INVOLVING RIGHT URETER: Positive for METASTASIS.

See note.

DIAGNOSIS COMMENT:

The resected tumoral nodules in #1, #3 through #10, shows serous papillary carcinoma with Grade 2 (in #3,4,6,8,10) and Grade 3 features (in #5,7,9).

FROZEN SECTION DIAGNOSIS:

FS1 OMENTUM WITH TUMOR:

Poorly differentiated carcinoma with psammoma bodies suggestive of papillary serous carcinoma. Tissue sent for ER/PR, tissue procurement.

Diagnosis by [REDACTED] Attending and [REDACTED] Fellow.

Diagnosis called [REDACTED]

GROSS DESCRIPTION:

1. OMENTUM WITH TUMOR: Received fresh and labelled "omentum with tumor" is an irregular shaped piece of red-tan, firm, nodular tissue measuring 27.0x17.0x3.5cm. Multiple sections show areas of soft, mucoid material admixed with tan, firm tissue infiltrating yellow adipose tissue. Touch preps are taken.

Sections are submitted as follows:

FS1=representative of tissue

AT-A5=representatives of tissue for permanent sections

2. UTERUS, TUBES & OVARIES, BILATERAL OVARIAN TUMORS, UPPER HALF OF VAGINA, PARAMETRIUM, CUL DE SAC WITH TUMOR: The specimen consists of the uterus with bilaterally attached adnexae, vagina, parametria and peritoneal tissue. The uterus measures 7.0x4.5x3.3cm; right and left ovarian tumors measure 7.5x6.0x3.5 cm and 6.0x5.0x3.0cm respectively; right and left tubes measure 6.0x0.4cm and 5.0x 0.4cm respectively; upper vaginal cuff measures 2.0cm in length; parametrial tissue measures 5.0 cm in width; and three fragments from the cul de sac measure 2.5x1.5x0.8 cm in aggregate.

Both ovaries are enlarged and replaced by granular tannish [REDACTED]

[page 3 of 4]
[REDACTED]

solid tumor with scattered necrotic areas. The left ovary show few cystic areas with smooth inner lining, ranging from 0.7cm to 1.5cm in diameter. The parametria, tubes, cul de sac uterine serosae and cervical walls are studded with delicate to shaggy tumorous lesions. The uterus shows two fibroids measuring 0.2 and 0.8 cm. The myometrium averages 2.8 cm in thickness. The endometrial cavity and endometrium are not remarkable.

Sections are submitted as follows:

AC1&AC2=anterior cervix with vaginal margin

PC1&PC2=posterior cervix with vaginal margin

AE=anterior endomyometrium

PE=posterior endomyometrium

MY1=leiomyoma of posterior wall

MY2=leiomyoma of anterior wall

RT=representatives of right fallopian tube

LT=representatives of left fallopian tube

TRO1-TRO5=representatives of right ovarian tumor with cyst material

TLO1-TLO5=representatives of left ovarian tumor

PM=representative of parametrium

TC=representative of tumor in cul de sac

3. TUMOR ANTERIOR RECTAL WALL: Received fresh and labelled "tumor anterior rectal wall" is a 3.5x2.5x0.5cm. piece of tan, granular, friable tissue. Representative sections are submitted in A.

4. BLADDER, PERITONEUM W/ TUMOR: Received fresh and labelled "bladder peritoneum with tumor" is a 6.5x3.5x0.8cm. piece of fatty tissue with numerous friable, tan, polypoid lesions on one surface. They range from 0.2cm. to 0.7cm. in diameter.

Representative sections are submitted in A.

5. DESCENDING COLON & RECTAL SIGMOID: Received fresh and labelled "descending colon and rectal sigmoid epiploica with tumor" are 8 pieces of fatty tissue aggregating to 7.0x5.0x2.0cm. Polypoid,

friable, tan lesions are present in all pieces, ranging from 0.2cm. to 0.8cm. in diameter. Representative sections are submitted in A1 and A2.

6. OMENTAL TUMOR @ SPLEEN: Received fresh and labelled "omental tumor at spleen" is a piece of fatty tissue measuring 10.0x4.5x2.0cm. Contained within it is a friable, necrotic, tan material. Representatives are submitted in A1 through A3.

7. PROXIMAL JEJUNAL MESENTERIC NODULE: Received fresh and labelled "proximal jejunum mesenteric nodule" is a 0.4cm. diameter, firm, tan nodule. It is submitted in toto in A.

8. DISTAL ILEUM MESENTERIC NODULE: Received fresh and labelled "distal ileum mesenteric nodule" is a 0.7x0.5x0.2cm. soft,

[REDACTED]

[page 4 of 4]
friable, tan nodule. It is submitted in toto in A.

9. TUMOR FROM RIGHT HEPATIC FLEXURE: Received fresh and labelled "tumor from right hepatic flexure" are 7 fragments of fatty tissue aggregating to 8.0x6.0x2.0cm. On the outer surface and within the fragments is friable, tan, soft necrotic tissue.

Representatives of the fragments are submitted in A1 and A2.

10. TUMOR INVOLVING RIGHT URETER: Received fresh and labelled "tumor involving right ureter" is a 2.0x1.2x0.5cm. fragment of soft, friable, tan tissue. Representatives are submitted in A.

Source: NCI Genomic Data Commons file 34092f67-4f9b-4f6c-8e53-74a05d5682ff (TCGA-59-2350.6BD3F7A6-BB9C-42EA-8F20-94DB43B51BDE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).